Gene-level copy-number profile of tumor specimen TCGA-61-1998-01A from TCGA case TCGA-61-1998, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 48.9 years (17,855 days).
Specimen TCGA-61-1998-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.81bfda42-19a0-4b57-9373-556b084db6c4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1998-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/de993295-2405-4a86-affd-9b88625371c9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15,282; copy number 2: 36,798; copy number 3: 4,125; copy number 4: 2,640; copy number 5: 876; copy number 6: 98.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-1998-01A-01D-0663-01): tumor purity 0.72, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 974 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:161,600,438–198,222,513, 647 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr8:127,794,526–128,187,101, 1 gene, copy number 5 (within-gene range 4–5): PVT1.
- chr8:127,946,559–138,497,261, 113 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:139,096,305–145,066,685, 213 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,861. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
